Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5506, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5506-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 7.2. The patient also has a history of biopsy on [REDACTED]. This biopsy reveals: Prostatic adenocarcinoma, Gleason score 4 + 3 = 7 in the left needle biopsy; prostatic adenocarcinoma, Gleason score 4 + 5 = 9 in the right needle biopsy. The patient also has a history of [REDACTED]

PRE-OP DIAGNOSIS: Prostate Cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

FINAL DIAGNOSIS:**TCGA - EJ - 5506****PART 1:**

LYMPH NODES, RIGHT PELVIC, EXCISION -

MICROSCOPIC FOCUS OF METASTATIC PROSTATIC ADENOCARCINOMA IS PRESENT IN THE SUBCAPSULAR SINUS OF ONE OF FOUR (1/4) LYMPH NODES. THE METASTATIC FOCUS MEASURES APPROXIMATELY 0.2 MILLIMETERS. NO LYMPH NODE EXTRACAPSULAR EXTENSION IS IDENTIFIED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN THREE (0/3) LYMPH NODES.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 5+3= 8 WITH TERTIARY GLEASON GRADE OF 4. GLEASON GRADES 4/5 REPRESENT 50-60% OF THE EXAMINED CARCINOMA.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.0 cm.
- C. THE CARCINOMA INVOLVES 30% OF THE EXAMINED PROSTATE VOLUME.
- D. MULTIFOCAL ESTABLISHED EXTRACAPSULAR EXTENSION IS PRESENT IN THE RIGHT AND LEFT PERI SEMINAL VESICLE SOFT TISSUE, ANTERIOR LEFT BASE, POSTERIOR RIGHT APEX, POSTERIOR RIGHT BASE, POSTERIOR LEFT APEX, POSTERIOR LEFT MID AND POSTERIOR LEFT BASE (SLIDES 3A, 3C, 3R, 3S, 3U, 3V, 3W, AND 3X).
- E. CARCINOMA EXTENDS CLOSE TO SEVERAL PERICAPSULAR AND ONE APICAL RESECTION MARGIN. NO INTACT CARCINOMA IDENTIFIED AT AN INKED RESECTION MARGIN (SEE COMMENT).
- F. CARCINOMA EXTENSIVELY INFILTRATES SEMINAL VESICLES BILATERALLY (SLIDES 3A AND 3C). BILATERAL VASA DEFERENTIA ARE BENIGN.
- G. ABUNDANT PERINEURAL INVASION IS IDENTIFIED.
- H. ANGIOLYMPHATIC INVASION IS IDENTIFIED (SLIDES 3A, 3C).
- I. FOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3b N1 MX.
- K. TNM HISTOLOGIC GRADE = G3 - 4.
- L. NON-NEOPLASTIC PROSTATE TISSUE WITH NODULAR HYPERPLASIA.

COMMENT:**Part 3:**

There is multifocal, extensive extracapsular extension of the carcinoma both in the prostate and seminal vesicles. Carcinoma extends very close to several pericapsular surgical resection margins and also close to the left posterior distal (apical) urethral resection margin (slide 3L). No intact carcinoma cells are present at an inked margin. Close clinical / serum PSA follow up is recommended.

Part 4:

There is a small focus of prostatic adenocarcinoma present in the right posterior base. It is not clear if this is a soft tissue margin or not.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 7.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	5
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	8
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	51.77gm
TUMOR SIZE:	Maximum dimension: 2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - 1 or 2 foci in region of tumor
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Tumor involvement at margin unknown
LYMPH NODES EXAMINED:	7
LYMPH NODES POSITIVE:	1
EXTRANODAL EXTENSION:	Unknown
SIZE OF NODAL METASTASIS:	0.2mm
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Comment:

There is a tertiary Gleason grade 4 component present within the tumor. The specimen labeled "right posterior base" has a 0.5 mm focus of prostatic adenocarcinoma in extraprostatic soft tissue. It is not clear whether or not this focus is at a margin.

Source: NCI Genomic Data Commons file 85fd23c9-3298-4112-9cdf-adccaf6ef127 (TCGA-EJ-5506.4B6B88E5-B9F5-4BED-8320-B227A30BD1A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).